Somatic mutation profile of tumor specimen 0DM1JX from CCDI case PBBZMM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.5 years (1,992 days).
Specimen 0DM1JX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d848d76a-f2f2-4371-9487-e99fbf7a410e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM1JC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1db3e099-4cac-445f-b159-69acdb037203

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMCR8 | c.1430C>T p.T477M | Missense Mutation (SNP) | VAF 140/571 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs571482412, COSV100328962; called by muse, mutect2, varscan2
- ACACB | c.2247C>T p.N749= | Silent (SNP) | VAF 237/860 reads (28%) | catalogued as rs371854014; called by muse, mutect2, varscan2
